Gene-level copy-number profile of tumor specimen TCGA-23-1021-01B from TCGA case TCGA-23-1021, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.1 years (16,484 days).
Specimen TCGA-23-1021-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.c3f1fd36-fc3e-48f9-9d09-14d678126742.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1021-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/05255c4e-6c5f-428c-baaf-8c9e6ab6b325

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 278; copy number 2: 24,063; copy number 3: 8,477; copy number 4: 23,075; copy number 5: 2,365; copy number 6: 912; copy number 7: 132; copy number 8: 35; copy number 9: 477.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1021-01B-01D-0428-01): tumor purity 0.93, ploidy 1.54, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:43,213,801–43,305,538, 4 genes (within-gene range 0–2): AL133375.1, DNPH1, TTBK1, SLC22A7.
- chr15:53,946,709–53,984,010, 1 gene (within-gene range 0–4): AC084759.2.
- chr15:54,048,588–54,050,876, 1 gene: AC010867.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,921 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,996,086–177,920,152, 870 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:222,088,806–248,919,946, 659 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:239,401,436–242,160,153, 88 genes, copy number 5 (broad region; genes not listed).
- chr3:197,293,878–198,222,513, 35 genes, copy number 8: MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr5:21,750,673–33,298,066, 135 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:139,221,758–153,223,543, 383 genes, copy number 5 (broad region; genes not listed).
- chr7:117,275,451–148,420,998, 624 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:102,239,394–145,066,685, 648 genes, copy number 5–9 (broad region; genes not listed).
- chr10:44,712–23,133,804, 392 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr16:88,234,785–90,222,851, 87 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 278. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
